Gene-level copy-number profile of tumor specimen TCGA-43-7658-01A from TCGA case TCGA-43-7658, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.9 years (27,734 days).
Specimen TCGA-43-7658-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ad8af792-723b-416f-ab42-3357a1d4de4c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-7658-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cb3c5ab-f600-480c-8b8e-6cefee269393

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 77; copy number 2: 18,260; copy number 3: 23,941; copy number 4: 7,378; copy number 5: 5,131; copy number 6: 3,528; copy number 7: 108; copy number 8: 668; copy number 9: 45; copy number 10: 162; copy number 11: 172; copy number 12: 133; copy number 13: 2; copy number 14: 32; copy number 15: 94; copy number 16: 5; copy number 18: 8; copy number 22: 40; copy number 25: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-7658-01A-11D-2121-01): tumor purity 0.75, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,495 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,884,459–152,445,456, 134 genes, copy number 15–22 (within-gene range 6–22) (broad region; genes not listed).
- chr1:156,619,331–187,686,628, 729 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr3:84,638,405–84,947,061, 4 genes, copy number 7: LINC00971, AC117482.1, LINC02025, AC132660.2.
- chr4:67,701,209–68,080,952, 1 gene, copy number 11 (within-gene range 4–11): UBA6-AS1.
- chr4:67,820,876–68,497,604, 18 genes, copy number 11: TMPRSS11D, TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2, MTND2P41, TMPRSS11F, SYT14P1, FTLP10, TMPRSS11BNL, TMPRSS11B, AC098799.3, AC098799.1, AC098799.2, APOOP4, YTHDC1, MT2P1, TMPRSS11E.
- chr4:68,614,419–70,532,743, 68 genes, copy number 11 (broad region; genes not listed).
- chr4:71,062,667–76,112,802, 82 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr5:58,198–4,147,429, 95 genes, copy number 7 (broad region; genes not listed).
- chr6:144,706,733–144,708,497, 2 genes, copy number 12: AL513475.1, AL513475.2.
- chr7:68,020,235–71,713,600, 24 genes, copy number 7–9: AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75.
- chr7:72,969,696–73,005,922, 1 gene, copy number 12 (within-gene range 3–12): STAG3L3.
- chr7:72,983,360–73,832,693, 43 genes, copy number 12: Y_RNA, PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5, NCF1B, GTF2IRD2P1, POM121B, NSUN5, TRIM50, AC211485.1, FKBP6, RNU6-1080P, Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4.
- chr7:75,899,200–85,636,344, 124 genes, copy number 9–18 (within-gene range 2–18) (broad region; genes not listed).
- chr7:89,882,353–90,211,635, 4 genes, copy number 7 (within-gene range 2–7): STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1.
- chr7:90,312,496–91,271,326, 13 genes, copy number 8–16: AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1.
- chr7:91,320,128–91,321,103, 1 gene, copy number 16: NIPA2P1.
- chr7:95,772,506–96,119,995, 2 genes, copy number 13: DYNC1I1, AC002540.1.
- chr8:70,669,369–71,228,629, 1 gene, copy number 8 (within-gene range 3–8): AC015687.1.
- chr8:71,155,454–75,352,327, 77 genes, copy number 8 (broad region; genes not listed).
- chr8:76,406,654–78,558,503, 14 genes, copy number 8 (within-gene range 5–8): LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P.
- chr13:91,272,081–96,053,482, 58 genes, copy number 14–25 (within-gene range 5–25): PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24.

Autosomal genes at a single copy (total copy number 1): 77. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
